Gene-level copy-number profile of specimen HCM-CSHL-1096-C44-85B from HCMI case HCM-CSHL-1096-C44, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III.
Specimen HCM-CSHL-1096-C44-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7ca64d68-f0bf-449e-8e31-b9246c562076.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1096-C44-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/d7754410-1cbe-4bab-8c9f-0b9722faf8a0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 150; copy number 2: 5,580; copy number 3: 26,567; copy number 4: 18,972; copy number 5: 6,113; copy number 6: 675; copy number 7: 21; copy number 8: 767; copy number 9: 18; copy number 10: 18.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 824 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,872,463–89,907,246, 5 genes, copy number 7: IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34.
- chr6:128,580,113–128,761,808, 4 genes, copy number 8: EEF1DP5, Y_RNA, AL080315.1, Y_RNA.
- chr8:39,451,045–39,522,852, 1 gene, copy number 8: ADAM3A.
- chr9:12,134–41,480,548, 710 genes, copy number 8 (broad region; genes not listed).
- chr9:42,566,679–61,642,494, 33 genes, copy number 9–10: BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:61,789,143–63,143,401, 46 genes, copy number 7–8: RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4.
- chr9:63,317,067–63,333,091, 1 gene, copy number 7 (within-gene range 3–7): AQP7P1.
- chr9:64,369,394–64,889,063, 18 genes, copy number 8: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr20:10,753,278–10,765,286, 1 gene, copy number 8 (within-gene range 6–8): AL135937.1.
- chr22:18,533,646–18,577,968, 1 gene, copy number 7: PI4KAP1.
- chr22:18,623,339–18,625,289, 1 gene, copy number 7: SUSD2P2.
- chr22:18,773,665–18,843,399, 3 genes, copy number 10 (within-gene range 10–20): GGT3P, AC008132.2, E2F6P1.

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
